Somatic mutation profile of tumor specimen TCGA-CJ-5676-01A (aliquot TCGA-CJ-5676-01A-11D-1534-10) from TCGA case TCGA-CJ-5676, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 47.0 years (17,170 days).
Specimen TCGA-CJ-5676-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e76b01d-6dec-45bd-b2f5-9aa8599b17c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5676-11A (Solid Tissue Normal), aliquot TCGA-CJ-5676-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a45b991-ffb6-4b5e-9423-7b2796295a0f

The open-access MAF lists 71 somatic variants for this specimen: 53 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 35, Silent 18, Nonsense Mutation 7, Frame Shift Del 5, Frame Shift Ins 3, Splice Region 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 63/162 reads (39%) | hotspot (GDC flag); catalogued as rs5030818, CM941381, CM961432, COSV56542817, COSV56554019, COSV56564848; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAD2 | c.997G>T p.V333F (on ENST00000315906 / NM_001145400.2; = p.V415F on NM_139174.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV51894316; called by muse, mutect2, varscan2
- ADAMTS12 | c.2755C>A p.Q919K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV61263629; called by muse, varscan2
- ADGRF5 | c.3094G>A p.V1032I | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0.07); catalogued as COSV51937077; called by muse, mutect2, varscan2
- ADGRL3 | c.2153C>A p.A718D (on ENST00000506720 / NM_001322402.2; = p.A650D on NM_015236.6) | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV101547320, COSV72231243; called by muse, mutect2, varscan2
- ADGRV1 | c.5944dup p.S1982Ffs*2 | Frame Shift Ins (INS) | VAF 67/533 reads (13%) | catalogued as rs1554081619; called by mutect2, pindel, varscan2
- ADGRV1 | c.12695A>C p.K4232T | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV67990064; called by muse, mutect2, varscan2
- AHNAK | c.11815A>T p.K3939* | Nonsense Mutation (SNP) | VAF 39/131 reads (30%) | catalogued as COSV57221588; called by muse, mutect2, varscan2
- AMY2B | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 187/968 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as rs762651617, COSV63716122; called by muse, mutect2, varscan2
- C1orf94 | c.1675C>G p.L559V (on ENST00000488417 / NM_001134734.2; = p.L369V on NM_032884.5) | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV64914649; called by muse, mutect2
- CDK14 | c.332A>T p.E111V (on ENST00000380050 / NM_001287135.2; = p.E93V on NM_012395.3) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV56043217; called by muse, mutect2, varscan2
- CLGN | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 168/571 reads (29%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.895); catalogued as COSV57773118, COSV57775572; called by muse, mutect2, varscan2
- DAPK2 | c.1034G>T p.R345M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV56046812; called by muse, mutect2, varscan2
- DEFB129 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV55731753; called by muse, mutect2, varscan2
- DMXL1 | c.5059T>G p.S1687A | Missense Mutation (SNP) | VAF 87/615 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.336); catalogued as COSV60716570; called by muse, mutect2, varscan2
- EXPH5 | c.3439A>T p.M1147L | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV56199439, COSV56205111; called by muse, mutect2, varscan2
- F2RL2 | c.362T>G p.F121C | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as COSV56971338; called by muse, mutect2, varscan2
- FAF1 | c.1653G>A p.E551= | Splice Region (SNP) | VAF 162/488 reads (33%) | catalogued as COSV65641108; called by muse, mutect2, varscan2
- FAM221B | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1177191146, COSV65074791; called by muse, mutect2
- FCGR3B | c.62-2A>C p.X21_splice | Splice Site (SNP) | VAF 40/142 reads (28%) | catalogued as COSV54210900; called by muse, mutect2
- GLI1 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373249560, COSV57364723; called by muse, mutect2, varscan2
- HMGCS2 | c.299A>T p.E100V | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65568538; called by muse, mutect2, varscan2
- JAK2 | c.3289G>T p.E1097* | Nonsense Mutation (SNP) | VAF 121/408 reads (30%) | catalogued as COSV67635747; called by muse, mutect2, varscan2
- KIF4A | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs868121736, COSV65544552; called by muse, mutect2, varscan2
- KRTAP17-1 | c.184T>A p.C62S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | PolyPhen benign (0.007); catalogued as COSV100498539; called by muse, varscan2
- MUC17 | c.2927C>T p.S976L | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs760062564, COSV60291297; called by muse, mutect2
- MYO10 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 27/300 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs752462063, COSV72454467; called by muse, mutect2
- NCAM1 | c.758A>T p.Q253L | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV57520316; called by muse, mutect2
- NELFCD | c.245G>A p.G82E (on ENST00000602795; = p.G64E on NM_198976.4) | Missense Mutation (SNP) | VAF 140/652 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59747639; called by muse, mutect2, varscan2
- OGDHL | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs571841376, COSV65103583; called by muse, mutect2, varscan2
- PAIP2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 131/333 reads (39%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54526118; called by muse, mutect2
- PBRM1 | c.3892C>T p.Q1298* (on ENST00000296302 / NM_001366071.2; = p.Q1273* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 76/207 reads (37%) | catalogued as COSV56270502; called by muse, mutect2, varscan2
- PKHD1 | c.9668C>A p.S3223* | Nonsense Mutation (SNP) | VAF 58/179 reads (32%) | catalogued as COSV61884932, COSV61886241; called by muse, mutect2, varscan2
- RCSD1 | c.341T>A p.M114K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV63259852; called by muse, mutect2, varscan2
- SETD2 | c.5346G>A p.W1782* | Nonsense Mutation (SNP) | VAF 83/213 reads (39%) | catalogued as COSV57444120; called by muse, mutect2, varscan2
- SLC44A3 | c.1921A>G p.R641G (on ENST00000271227 / NM_001114106.3; = p.R593G on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54732018; called by muse, mutect2, varscan2
- SLX4 | c.2469G>A p.W823* | Nonsense Mutation (SNP) | VAF 40/396 reads (10%) | catalogued as rs1267428175, CM137057, COSV53566098; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.876G>C p.L292F | Missense Mutation (SNP) | VAF 101/352 reads (29%) | PolyPhen possibly damaging (0.902); catalogued as COSV56571964; called by muse, mutect2, varscan2
- TBX4 | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV53608447; called by muse, mutect2, varscan2
- TENT2 | c.360G>T p.L120F | Missense Mutation (SNP) | VAF 23/347 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV57138240; called by muse, mutect2
- TNIK | c.3086A>T p.N1029I | Missense Mutation (SNP) | VAF 52/563 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52688189, COSV52692960; called by muse, mutect2
- TRIM6-TRIM34 | c.1581G>C p.K527N | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV61457320; called by muse, mutect2, varscan2
- UGGT1 | c.3090C>A p.D1030E | Missense Mutation (SNP) | VAF 185/724 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52138583; called by muse, mutect2, varscan2
- ULK4 | c.3337G>C p.D1113H | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV57215064; called by muse, mutect2, varscan2
- XPO5 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs774916295, COSV54832610; called by muse, mutect2, varscan2
- ZNF165 | c.490C>G p.Q164E | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV66102761; called by muse, mutect2, varscan2
- APOOL | c.723_726del p.T242Sfs*19 | Frame Shift Del (DEL) | VAF 55/99 reads (56%) | called by mutect2, pindel, varscan2
- CHD2 | c.180del p.E61Rfs*33 | Frame Shift Del (DEL) | VAF 28/236 reads (12%) | called by mutect2, pindel
- GOT1 | c.248del p.C83Lfs*19 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | called by mutect2, pindel, varscan2
- PTPN6 | c.473del p.P158Qfs*61 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- SLC16A1 | c.749dup p.N250Kfs*36 | Frame Shift Ins (INS) | VAF 34/249 reads (14%) | called by mutect2, pindel, varscan2
- TMA7 | c.191del p.K64Sfs*19 | Frame Shift Del (DEL) | VAF 134/412 reads (33%) | called by mutect2, pindel, varscan2
- WDFY3 | c.9360dup p.Q3121Tfs*8 | Frame Shift Ins (INS) | VAF 60/364 reads (16%) | called by pindel, varscan2
- CCDC144A | c.2097C>T p.Y699= | Silent (SNP) | VAF 20/626 reads (3%) | catalogued as rs1446130650, COSV60700001; called by muse, mutect2
- CLCN6 | c.1596G>T p.G532= | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as COSV56741693; called by muse, mutect2, varscan2
- GEMIN5 | c.4077C>T p.L1359= | Silent (SNP) | VAF 97/420 reads (23%) | catalogued as COSV53562495, COSV53562890; called by muse, mutect2, varscan2
- GREB1 | c.327G>A p.E109= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs759844334, COSV52191661; called by muse, mutect2, varscan2
- INO80 | c.3762C>T p.F1254= | Silent (SNP) | VAF 58/195 reads (30%) | catalogued as COSV62740228; called by muse, mutect2, varscan2
- NAV3 | c.1788C>T p.S596= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV57095627; called by muse, mutect2, varscan2
- PIANP | c.159G>A p.S53= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs780349942, COSV57708222; called by muse, mutect2
- PIWIL1 | c.1122G>T p.G374= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs758988547, COSV55349124; called by muse, mutect2, varscan2
- POFUT2 | c.858C>T p.G286= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as rs1231709154, COSV57959210; called by muse, mutect2, varscan2
- SDC1 | c.474G>A p.Q158= | Silent (SNP) | VAF 70/211 reads (33%) | catalogued as COSV54340725; called by muse, mutect2, varscan2
- SPOUT1 | c.684T>A p.T228= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV63509581; called by muse, mutect2, varscan2
- TEX2 | c.3228C>T p.D1076= (on ENST00000583097 / NM_001288733.2; = p.D1083= on NM_018469.5) | Silent (SNP) | VAF 77/556 reads (14%) | catalogued as COSV51983340; called by muse, mutect2, varscan2
- TPP2 | c.777C>T p.T259= | Silent (SNP) | VAF 112/399 reads (28%) | catalogued as COSV65753699; called by muse, mutect2, varscan2
- TPR | c.3969A>C p.A1323= | Silent (SNP) | VAF 122/732 reads (17%) | catalogued as rs376859703, COSV66603043; called by muse, mutect2
- UPB1 | c.426A>G p.A142= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as rs1426487441, COSV58112140; called by muse, mutect2
- UTRN | c.4149G>A p.E1383= | Silent (SNP) | VAF 48/205 reads (23%) | catalogued as COSV62341135; called by muse, mutect2, varscan2
- YAP1 | c.400T>C p.L134= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV56776781; called by muse, mutect2
- ZNF300 | c.378A>G p.K126= | Silent (SNP) | VAF 109/298 reads (37%) | catalogued as COSV51040915; called by muse, varscan2
